Somatic mutation profile of tumor specimen BA3413D (aliquot aq-BA3413D) from BEATAML1.0 case 2666, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 31.2 years (11,382 days).
Specimen BA3413D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0445c5e-82f7-4d33-ad91-396bb15ec9d3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3104D (Solid Tissue Normal), aliquot aq-BA3104D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3bd62f9-edd6-41fd-8ad6-e070005766c3

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN6 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV100136996; called by muse, mutect2, varscan2
- GATA2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62002969, COSV62003176; called by muse, mutect2, varscan2
- NCOR1 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 65/150 reads (43%) | catalogued as COSV99247836; called by muse, mutect2, varscan2
- CEBPA | c.956_961del p.S319_D320del | In Frame Del (DEL) | VAF 24/56 reads (43%) | called by mutect2, varscan2
- CILP | c.3289G>A p.D1097N | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATP2B2 | c.3222G>A p.P1074= (on ENST00000352432; = p.P1040= on NM_001683.5) | Silent (SNP) | VAF 51/102 reads (50%) | catalogued as rs778841319; called by muse, mutect2, varscan2
- IRX1 | c.969C>A p.A323= | Silent (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- SLC9A3 | c.96C>T p.P32= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs1411548397; called by muse, mutect2, varscan2
- TACC2 | c.885G>A p.A295= | Silent (SNP) | VAF 88/172 reads (51%) | catalogued as rs781422767; called by muse, mutect2, varscan2
